TCGA case TCGA-YF-AA3M — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Puerto Rico. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/30ad8081-daa7-4e2b-96f8-07f5ad12e774

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Country of residence at enrollment: Puerto Rico; Age at index: 57 years; Vital status: Alive.

Diagnoses (6)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.2; Tissue or organ of origin: Lateral wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 57.8 years (21,097 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 56.6 years (20,690 days); Days to diagnosis: -407 days (-1.1 years); AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -412 days (-1.1 years); Treatment anatomic sites: Bladder.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: BCG Solution; Days to treatment start: -294 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: BCG Solution; Treatment intent type: Induction; Timepoint category: Prior to Procurement.
4. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2c.
5. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Laterality: Bilateral; Classification of tumor: Synchronous primary; Age at diagnosis: 58.1 years (21,219 days); Days to diagnosis: 122 days; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 99 days; Treatment anatomic sites: Prostate / Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
6. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Pelvis, NOS. Age at diagnosis: 58.8 years (21,478 days); Days to diagnosis: 381 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 275 days; Disease response: Tumor Free.
- Day 381 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 381 days (1.0 years).
- Days to follow up: 415 days (1.1 years); Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 168 cm; BMI: 27.3.

Exposures
- Occupation duration years: 15; Occupation type: Heavy Truck and Bus Drivers.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 58; Age at onset: 16.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YF-AA3M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 360 mg.
  Slide TCGA-YF-AA3M-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample TCGA-YF-AA3M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YF-AA3M-10D: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: Yes; Tumor status: Tumor free; Occupation current: Disabled; Occupation primary: Truck Driver; Occupation primary industry: Master Concrete Company; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: No; Lymphovascular invasion: No; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2c; Treatment outcome first course: Complete Remission/Response.
- Stage record, Gleason grading: Gleason score: 6.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Bacillus Calmette-Guerin (BCG); Bcg treatment 90 days prior to resection: No; Bcg treatment complete response: No; Bcg treatment induction courses indicator: Yes; Bcg treatment maintenance courses indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Radical Cystoprostatectomy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: High Grade Invasive Urothelial Carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Transurethral Resection of Bladder Tumro (TURBT).
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Bacillus Calmette Guerin (BCG).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 415 days; disease-specific survival: no event (censored), 415 days; disease-free interval: event (new tumor event after initially disease-free), 381 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 381 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YF-AA3M-01A-11D-A42D-01): tumor purity 0.68, ploidy 4.75, whole-genome doublings 2.
